Somatic mutation profile of tumor specimen MMRF_2745_1_BM_CD138pos (aliquot MMRF_2745_1_BM_CD138pos_T1_KHS5U_L14899) from MMRF case MMRF_2745, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.5 years (23,549 days).
Specimen MMRF_2745_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d92d7f2a-e3e0-4149-b640-40eb3591ac8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2745_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2745_1_PB_WBC_C3_KHS5U_L14900; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6653209a-9222-4f04-b5fe-c658a64d49e5

The open-access MAF lists 254 somatic variants for this specimen: 83 protein-altering or splice-affecting, 26 silent, 145 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 87, Missense Mutation 67, Intron 33, Silent 26, 5'UTR 15, Splice Region 6, 3'Flank 5, Nonsense Mutation 4, 5'Flank 3, Splice Site 3, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRA | c.1068A>T p.K356N | Missense Mutation (SNP) | VAF 80/99 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732759; called by muse, mutect2, varscan2
- ARHGAP10 | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs780717500, COSV100330907; called by muse, mutect2, varscan2
- B3GAT2 | c.885+8T>G | Splice Region (SNP) | VAF 205/452 reads (45%) | catalogued as COSV100017308; called by muse, mutect2, varscan2
- CAPN6 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 78/101 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs962047296; called by muse, mutect2, varscan2
- CDH10 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV52593283; called by muse, mutect2, varscan2
- CDK17 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV54130725, COSV99702821; called by muse, mutect2, varscan2
- COL9A1 | c.2090G>A p.G697E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294484; called by muse, mutect2
- DLGAP3 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52391674; called by muse, mutect2
- DNAH7 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV100413584, COSV99044790; called by muse, mutect2, varscan2
- DUSP7 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs780762848; called by muse, mutect2, varscan2
- ELP4 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1212967030, COSV99540664; called by muse, mutect2
- EPN3 | c.1838C>A p.T613K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs1292914288; called by muse, mutect2, varscan2
- FAM186A | c.3959C>T p.A1320V | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs551324592; called by muse, mutect2, varscan2
- FDFT1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1388946948; called by muse, mutect2
- GPC5 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65579651; called by muse, mutect2, varscan2
- IGLV1-47 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.566); catalogued as rs527799688; called by muse, mutect2, varscan2
- IGLV4-60 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs78099525; called by muse, mutect2, varscan2
- IGLV5-45 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.164); catalogued as rs61731378; called by muse, varscan2
- IGLV5-45 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 143/226 reads (63%) | catalogued as rs544739530; called by muse, varscan2
- KRAS | c.71T>A p.I24N | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55516232; called by muse, mutect2, varscan2
- KRT79 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs143513246; called by muse, mutect2, varscan2
- LINGO2 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.863); catalogued as rs775438948, COSV58056709; called by muse, mutect2, varscan2
- LRP2 | c.5072C>T p.A1691V | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0.017); catalogued as rs145365776, COSV104378305; called by muse, mutect2, varscan2
- NCOR1 | c.2182+2T>A p.X728_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV51976957; called by muse, mutect2, varscan2
- PCDH15 | c.3355C>T p.L1119F | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV57368190; called by muse, mutect2, varscan2
- PCLO | c.9109G>A p.D3037N | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421280482; called by muse, mutect2, varscan2
- PGBD1 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.142); catalogued as rs1469232005; called by muse, mutect2, varscan2
- SLC4A10 | c.859-7C>T | Splice Region (SNP) | VAF 31/58 reads (53%) | catalogued as rs776921014; called by muse, varscan2
- SLC4A11 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757935850; called by muse, mutect2, varscan2
- SLITRK1 | c.1842G>C p.R614S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs1173357558, COSV101000051; called by muse, mutect2, varscan2
- SUZ12 | c.823+2T>C p.X275_splice | Splice Site (SNP) | VAF 31/78 reads (40%) | catalogued as COSV59498656; called by mutect2, varscan2
- TSC22D2 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313382478; called by muse, mutect2, varscan2
- Z83844.2 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs767287967; called by muse, mutect2, varscan2
- ZNF841 | c.119C>T p.P40L (on ENST00000426391 / NM_001369830.1; = p.P156L on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); catalogued as rs759770352; called by muse, mutect2, varscan2
- ZSWIM5 | c.2782G>A p.V928I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs752302467; called by muse, mutect2, varscan2
- ABCD2 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANAPC2 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- CNTNAP2 | c.3381+1G>A p.X1127_splice | Splice Site (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2, varscan2
- DCLK2 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DGKB | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DIS3 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FABP9 | c.165_187del p.E55Dfs*10 | Frame Shift Del (DEL) | VAF 38/56 reads (68%) | called by mutect2, pindel, varscan2
- FILIP1 | c.2722C>T p.Q908* | Nonsense Mutation (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- GBF1 | c.4109T>G p.L1370R (on ENST00000369983 / NM_001377137.1; = p.L1369R on NM_004193.3) | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- GLUD1 | c.1439A>C p.K480T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, varscan2
- GPR139 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD2 | c.939T>G p.I313M | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- IGLV5-45 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, varscan2
- IK | c.483T>A p.H161Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IRS2 | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- KDM3A | c.2923-7C>T | Splice Region (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- KHSRP | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2
- KRT12 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MAPKAPK5 | c.1326T>C p.N442= (on ENST00000551404 / NM_139078.3; = p.N440= on NM_003668.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- MARVELD3 | c.1199A>C p.E400A | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MRPS5 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYCN | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYSM1 | c.1038T>G p.I346M | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NEUROG3 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OSMR | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGM | c.740A>T p.Y247F | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PTPN22 | c.2140C>T p.Q714* (on ENST00000359785 / NM_001193431.2; = p.Q659* on NM_012411.5) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- PUS7L | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.011); called by muse, mutect2
- RAB11FIP4 | c.1532A>C p.Q511P | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RAB3GAP1 | c.2365_2366dup p.L790Yfs*4 | Frame Shift Ins (INS) | VAF 36/106 reads (34%) | called by mutect2, pindel, varscan2
- RAP1GAP | c.1909G>C p.G637R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX7 | c.2593C>T p.P865S (on ENST00000559447 / NM_001368074.1; = p.P962S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROS1 | c.5464C>A p.L1822M | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RTN4IP1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SARS2 | c.962+7C>G | Splice Region (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- SEMA5B | c.2788C>T p.H930Y | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SF3A1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SGIP1 | c.1571-4A>C | Splice Region (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- SMARCA5 | c.2093_2104del p.S698_R701del | In Frame Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- SPG11 | c.3284T>G p.V1095G | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TGFBR1 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAV34 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TRIM62 | c.1285T>C p.F429L | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TTN | c.81653A>C p.K27218T (on ENST00000591111; = p.K19794T on NM_003319.4) | Missense Mutation (SNP) | VAF 68/201 reads (34%) | PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TUT7 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 277/611 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UGT2B15 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- YBX3 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF574 | c.2491T>C p.Y831H | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ACTR1A | c.549C>T p.I183= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs1414412222; called by muse, mutect2, varscan2
- APBB2 | c.2079C>T p.N693= (on ENST00000295974 / NM_001166050.2; = p.N694= on NM_004307.2) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs548111352, COSV55962845; called by muse, mutect2, varscan2
- ARHGAP24 | c.480G>T p.V160= (on ENST00000395184 / NM_001025616.3; = p.V67= on NM_031305.3) | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- ARSG | c.849C>A p.I283= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as COSV101477930; called by muse, mutect2, varscan2
- BMP6 | c.744T>C p.G248= | Silent (SNP) | VAF 79/156 reads (51%) | called by muse, mutect2, varscan2
- CCDC130 | c.222G>A p.K74= | Silent (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- CD1E | c.489C>T p.I163= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs1321012519; called by muse, mutect2, varscan2
- CFAP251 | c.1227A>G p.E409= | Silent (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- DNAJC13 | c.3696A>T p.A1232= | Silent (SNP) | VAF 115/276 reads (42%) | catalogued as COSV99606807; called by muse, mutect2, varscan2
- EEA1 | c.2790A>G p.K930= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- EFHB | c.156G>A p.K52= | Silent (SNP) | VAF 24/253 reads (9%) | called by muse, mutect2
- EFTUD2 | c.1314C>A p.I438= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV68183918; called by muse, mutect2, varscan2
- FBXO10 | c.798G>A p.K266= | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- IGLV5-45 | c.174G>A p.Q58= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as rs375850965; called by muse, varscan2
- MAGEB18 | c.303C>A p.G101= | Silent (SNP) | VAF 70/83 reads (84%) | called by muse, mutect2, varscan2
- MGARP | c.45G>A p.L15= | Silent (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- MSX1 | c.816C>T p.Y272= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs375828884, COSV66947420; called by mutect2, varscan2
- NEURL1B | c.603G>A p.T201= | Silent (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- NRM | c.684G>A p.L228= | Silent (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- OBSCN | c.9753C>T p.S3251= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs538035634, COSV99472225; called by muse, mutect2, varscan2
- RAB18 | c.357A>C p.L119= | Silent (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.366T>C p.A122= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- SINHCAF | c.372T>C p.S124= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as rs1245789871; called by muse, mutect2, varscan2
- SLC34A2 | c.1686C>T p.V562= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as rs114501307, COSV65943401; called by muse, mutect2, varscan2
- TXNDC8 | c.297T>C p.Y99= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as rs745843543; called by muse, mutect2, varscan2
- USF3 | c.3432G>A p.E1144= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- ABCC10 | c.*256C>G | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- ACTL10 | c.-727_-710del | 5'UTR (DEL) | VAF 42/118 reads (36%) | called by mutect2, pindel, varscan2
- ALDH1A3 | c.99+1189C>T | Intron (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- AMMECR1 | c.*4252T>C | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1892-568G>A | Intron (SNP) | VAF 49/139 reads (35%) | called by muse, mutect2, varscan2
- ANKMY1 | c.213+44G>T | Intron (SNP) | VAF 76/187 reads (41%) | called by muse, mutect2, varscan2
- ANKRD13C | chr1:70354886 C>A | 5'Flank (SNP) | VAF 42/126 reads (33%) | catalogued as rs557849190; called by muse, mutect2, varscan2
- ANKRD28 | c.*285A>G | 3'UTR (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- ANXA5 | c.*55T>C | 3'UTR (SNP) | VAF 12/231 reads (5%) | catalogued as rs1164218859; called by muse, mutect2
- AQP1 | c.385-245G>A | Intron (SNP) | VAF 31/61 reads (51%) | catalogued as rs780966313; called by muse, mutect2, varscan2
- AQR | c.76-66G>C | Intron (SNP) | VAF 53/301 reads (18%) | called by muse, mutect2, varscan2
- ARL1 | c.*2433A>C | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- ATXN7L3B | c.*2571T>C | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- C1orf43 | chr1:154220634 C>G | 5'Flank (SNP) | VAF 11/236 reads (5%) | called by muse, mutect2
- CALHM5 | c.*4606G>C | 3'UTR (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- CARD8 | c.*803C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- CCNT2 | c.774+189T>G | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- CCT5 | c.-45A>T | 5'UTR (SNP) | VAF 92/201 reads (46%) | called by muse, mutect2, varscan2
- CD276 | c.*739T>A | 3'UTR (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- CDC27 | c.*926T>A | 3'UTR (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- CDK10 | c.*47C>T | 3'UTR (SNP) | VAF 63/180 reads (35%) | catalogued as rs1416488515; called by muse, mutect2, varscan2
- CDK11A | chr1:1724842 G>T | 5'Flank (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- CFL2 | c.*1695G>C | 3'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CHERP | c.26-18C>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs754359322, COSV52228051; called by muse, mutect2
- CHST2 | c.*509A>G | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- CMC1 | c.*1228C>T | 3'UTR (SNP) | VAF 39/100 reads (39%) | catalogued as rs968399964; called by muse, mutect2, varscan2
- CMPK1 | c.*416C>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- COL4A3 | c.*2517T>C | 3'UTR (SNP) | VAF 24/64 reads (38%) | catalogued as rs1039502419; called by muse, mutect2, varscan2
- CR1 | c.*308C>T | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- CRNKL1 | c.*127T>G | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- CS | c.*594T>A | 3'UTR (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*3697T>C | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- DDX27 | c.*12T>A | 3'UTR (SNP) | VAF 99/222 reads (45%) | called by muse, mutect2, varscan2
- DLG4 | c.-170C>T | 5'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- DPYD | c.*249A>C | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2
- DTD2 | c.*871A>G | 3'UTR (SNP) | VAF 5/14 reads (36%) | catalogued as rs912509125; called by muse, mutect2, varscan2
- EIF2S1 | c.*36G>C | 3'UTR (SNP) | VAF 21/207 reads (10%) | catalogued as rs533452032; called by muse, mutect2, varscan2
- EIF5A2 | c.*4277A>C | 3'UTR (SNP) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- ELAPOR2 | c.*409T>A | 3'UTR (SNP) | VAF 47/127 reads (37%) | called by muse, mutect2, varscan2
- ENPP4 | c.*640A>C | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- EXPH5 | c.-52C>A | 5'UTR (SNP) | VAF 163/358 reads (46%) | called by muse, mutect2, varscan2
- FBH1 | c.-54C>T | 5'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- FBRSL1 | c.*1061C>A | 3'UTR (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- FCRLA | c.569-90G>A | Intron (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105357747 T>G | 3'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- FSTL1 | c.*3402G>T | 3'UTR (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
- GAB2 | c.*3833A>T | 3'UTR (SNP) | VAF 49/126 reads (39%) | catalogued as rs1210192752; called by muse, mutect2, varscan2
- GALNT17 | c.-465G>T | 5'UTR (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- GASK1B | c.*1850A>C | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- GET4 | c.156-1394G>A | Intron (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- GGA2 | c.*54G>A | 3'UTR (SNP) | VAF 9/241 reads (4%) | called by muse, mutect2
- GNAL | chr18:11883855 T>A | 3'Flank (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- GRID2 | c.-345C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- H4C4 | c.*1G>C | 3'UTR (SNP) | VAF 37/76 reads (49%) | catalogued as rs376927129; called by muse, mutect2, varscan2
- HDAC5 | c.23-440C>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+1374G>A | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- HGF | c.*383dup | 3'UTR (INS) | VAF 49/130 reads (38%) | called by mutect2, pindel, varscan2
- HMGB4 | c.-457C>T | 5'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.485T>C | RNA (SNP) | VAF 160/392 reads (41%) | called by muse, mutect2, varscan2
- HTR1F | c.*482_*484del | 3'UTR (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- IFT46 | c.673-1322A>T | Intron (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
- IL6ST | c.*4372T>A | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- IP6K1 | c.*1486C>T | 3'UTR (SNP) | VAF 5/114 reads (4%) | called by muse, mutect2
- ITGB5 | c.*1472T>C | 3'UTR (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- JKAMP | c.*418T>C | 3'UTR (SNP) | VAF 34/45 reads (76%) | catalogued as rs73303700; called by muse, mutect2, varscan2
- KCTD10 | c.*577G>A | 3'UTR (SNP) | VAF 51/132 reads (39%) | called by muse, mutect2, varscan2
- KCTD6 | c.-859T>G | 5'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*5110T>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs377360887, COSV63291006; called by muse, varscan2
- KRAS | c.*3067T>G | 3'UTR (SNP) | VAF 46/75 reads (61%) | called by muse, mutect2, varscan2
- LASP1 | c.*1119C>T | 3'UTR (SNP) | VAF 31/64 reads (48%) | catalogued as rs985350637; called by muse, mutect2, varscan2
- LECT2 | c.289+354T>C | Intron (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- LLCFC1 | c.*187T>C | 3'UTR (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- MAD2L2 | c.231+45_231+64del | Intron (DEL) | VAF 23/84 reads (27%) | called by mutect2, varscan2
- MAP3K7 | c.-133C>T | 5'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs922056529; called by muse, mutect2, varscan2
- MGST1 | c.*213_*214del | 3'UTR (DEL) | VAF 25/61 reads (41%) | called by pindel, varscan2
- MPEG1 | c.*1650T>A | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- MRPL45 | c.*207T>C | 3'UTR (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- MTREX | c.3077-728T>A | Intron (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- MUC20 | chr3:195741093 A>G | 3'Flank (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- MXD4 | c.*1317C>A | 3'UTR (SNP) | VAF 111/254 reads (44%) | called by muse, mutect2, varscan2
- MYEF2 | c.*1560C>T | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2
- NADK2 | c.1191-85A>T | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- NANOGNB | c.*134G>A | 3'UTR (SNP) | VAF 42/97 reads (43%) | catalogued as rs1039811035; called by muse, mutect2, varscan2
- NAV1 | c.*3950T>C | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- NDST3 | c.*258C>G | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1398G>C | 3'UTR (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- NTRK1 | c.1501+90C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs146573823; called by muse, mutect2, varscan2
- NTRK2 | c.1585+8526G>A | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- OR51S1 | c.*11C>T | 3'UTR (SNP) | VAF 111/286 reads (39%) | called by muse, mutect2, varscan2
- P4HB | c.*776C>T | 3'UTR (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- PAPPA | c.*4325A>G | 3'UTR (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- PBX1 | c.*3422A>C | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- PBX1 | c.*5155T>G | 3'UTR (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- PCBP3 | c.717+244T>G | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- PDE3A | c.*1798T>C | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- PDGFC | c.-233G>T | 5'UTR (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1579+214T>G | Intron (SNP) | VAF 27/37 reads (73%) | called by muse, mutect2, varscan2
- POLR2J | c.*68T>C | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*4773C>A | 3'UTR (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- PRPF40A | c.*1279T>A | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- PRR9 | c.*506C>T | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2
- PRR9 | c.*508C>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2
- PSMB10 | c.243-19A>G | Intron (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- PTPRJ | c.1615+1249T>G | Intron (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- RAB17 | c.157+509C>G | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs935982443; called by muse, mutect2
- RACK1 | c.-12C>T | 5'UTR (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100958673; called by muse, mutect2, varscan2
- RALGDS | c.*550C>T | 3'UTR (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- RNF141 | c.*196A>G | 3'UTR (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- RRAGD | c.*1870T>A | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- SARS1 | c.*242C>T | 3'UTR (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- SDHC | c.-20C>T | 5'UTR (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100337812; called by muse, mutect2
- SH2D4B | chr10:80644305 A>T | 3'Flank (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- SLC45A3 | c.*483G>A | 3'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- SLC66A3 | c.-60C>T | 5'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs1251362938; called by muse, mutect2
- SLU7 | c.*1021T>C | 3'UTR (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- SNRNP40 | c.921-22T>C | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- SOX9 | c.*370G>A | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- SPRY3 | c.*5032A>G | 3'UTR (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- SRGAP2 | c.2504+640T>G | Intron (SNP) | VAF 76/171 reads (44%) | called by muse, mutect2, varscan2
- SSPOP | n.7548T>G | RNA (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- SSR1 | c.*2923T>G | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ST3GAL1 | c.*3373G>A | 3'UTR (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- STX1B | c.*673G>C | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- SULT1A1 | c.-4-327G>A | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1464858750; called by muse, mutect2
- TAF8 | c.*4644A>G | 3'UTR (SNP) | VAF 36/94 reads (38%) | catalogued as rs1329268538; called by muse, mutect2, varscan2
- TFAM | c.*994A>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | catalogued as COSV65876585; called by muse, mutect2
- TMEM154 | c.*2428A>C | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- TMEM203 | c.*888A>C | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2
- TMEM9B | c.441+359_441+360del | Intron (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2
- TNNT2 | c.199+66A>C | Intron (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- TNRC6B | c.*5688T>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- TP73 | c.*1280C>T | 3'UTR (SNP) | VAF 14/158 reads (9%) | catalogued as rs1050642011; called by muse, mutect2
- TRIM41 | c.-597C>G | 5'UTR (SNP) | VAF 42/95 reads (44%) | catalogued as rs972370694; called by muse, mutect2, varscan2
- TTBK2 | c.823-6587G>T | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- TXNL1 | c.*2223T>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- UGT3A2 | c.*343G>A | 3'UTR (SNP) | VAF 23/35 reads (66%) | catalogued as rs964603958; called by muse, mutect2, varscan2
- USP25 | chr21:15880051 G>C | 3'Flank (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- UTP23 | c.189-48A>C | Intron (SNP) | VAF 44/56 reads (79%) | catalogued as rs1408943495; called by mutect2, varscan2
- VPS33B | c.779-16C>G | Intron (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- WTAP | c.452+297G>T | Intron (SNP) | VAF 18/263 reads (7%) | called by muse, mutect2
- WWC2 | c.*2039G>C | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- ZBTB1 | c.*21T>A | 3'UTR (SNP) | VAF 23/28 reads (82%) | called by muse, mutect2, varscan2
- ZNF217 | c.3037+49T>A | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2
- ZNF689 | c.*273T>G | 3'UTR (SNP) | VAF 95/217 reads (44%) | called by muse, mutect2, varscan2
- ZYG11A | c.*1411T>G | 3'UTR (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
